CCDI case PBBVNR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/9de7bf90-541f-47cb-9e1c-4cc97f23b1ce

Demographics
Sex at birth: male; Vital status: Alive.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 14.2 years (5,169 days).

Biospecimens (3 samples)
- Sample 0DIMVS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMX0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
